Somatic mutation profile of tumor specimen TCGA-CZ-5458-01A (aliquot TCGA-CZ-5458-01A-01D-1501-10) from TCGA case TCGA-CZ-5458, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 43.2 years (15,790 days).
Specimen TCGA-CZ-5458-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09f7f5b8-e129-4388-8a5b-bf450986c232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5458-11A (Solid Tissue Normal), aliquot TCGA-CZ-5458-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae6e437e-9671-48ed-af3d-f10d4e9d3331

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT1 | c.6218A>G p.K2073R | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs751949269, COSV55316732; called by muse, mutect2, varscan2
- CRB1 | c.3892A>C p.I1298L | Missense Mutation (SNP) | VAF 149/612 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV66330429; called by muse, mutect2, varscan2
- ETF1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 72/165 reads (44%) | catalogued as COSV62127327; called by muse, mutect2, varscan2
- GALR1 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs1568376740, COSV55317085; called by muse, mutect2, varscan2
- KAT5 | c.285+2T>G p.X95_splice | Splice Site (SNP) | VAF 13/40 reads (33%) | catalogued as COSV57729619; called by muse, mutect2, varscan2
- MARCHF10 | c.1882A>T p.K628* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV60887259; called by muse, mutect2, varscan2
- NKAIN3 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 296/1189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60661202; called by muse, mutect2, varscan2
- NUAK2 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65681521; called by muse, mutect2, varscan2
- PKHD1L1 | c.7135T>C p.F2379L | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV65743051; called by muse, mutect2, varscan2
- RAB11FIP3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51933519; called by muse, mutect2, varscan2
- RNF25 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55307409; called by muse, mutect2, varscan2
- SLC35A5 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV53726786; called by muse, mutect2, varscan2
- SPATA33 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV53683274; called by muse, mutect2, varscan2
- SPTA1 | c.1323T>A p.H441Q | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63753225; called by muse, mutect2, varscan2
- STAT2 | c.742A>G p.R248G | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58475510; called by muse, mutect2
- TRA2B | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV52025390; called by muse, mutect2, varscan2
- UBE3C | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 185/761 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61953235; called by muse, varscan2
- UNC50 | c.560C>G p.T187R | Missense Mutation (SNP) | VAF 207/922 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV53847240; called by muse, mutect2, varscan2
- VHL | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040270, CM093522, COSV56544329, COSV56550485, COSV56556920; called by muse, mutect2, varscan2
- ZNF200 | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV67723827; called by muse, mutect2
- CFL1 | c.445del p.L149Wfs*81 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- MAGT1 | c.39C>A p.T13= (on ENST00000618282 / NM_001367916.1; = p.T45= on NM_032121.5) | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV63781706; called by muse, mutect2, varscan2
- NBEAL2 | c.2019C>G p.A673= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV52757821, COSV99436371; called by muse, mutect2, varscan2
- NLRP14 | c.510C>G p.V170= | Silent (SNP) | VAF 12/275 reads (4%) | catalogued as COSV55067225; called by muse, mutect2
- NT5C3A | c.868C>T p.L290= (on ENST00000610140 / NM_001374335.1; = p.L256= on NM_016489.13) | Silent (SNP) | VAF 110/399 reads (28%) | catalogued as COSV54238250; called by muse, mutect2, varscan2
- RDH16 | c.786G>A p.S262= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs372244884; called by muse, mutect2, varscan2
- RYR3 | c.1563C>T p.Y521= | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as COSV66789690; called by muse, mutect2
- CTSL3P | n.204C>A | RNA (SNP) | VAF 64/273 reads (23%) | called by muse, mutect2, varscan2
